Surgical pathology report (de-identified scan), TCGA case TCGA-06-0221, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0221-02A (Recurrent Tumor).

[page 1 of 2]
PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: M DOB:

SURGERY DATE:

RECEIVE DATE:

PHYSICIAN:

COPY TO:

UPDATED REPORT - SEE ADDENDUM REPORT, ADDENDUM DIAGNOSIS
UPDATED REPORT - SEE SPECIAL STAIN REPORT

PATHOLOGICAL DIAGNOSIS:

A. BRAIN, FRONTAL, EXCISIONAL BIOPSY: MALIGNANT GLIOMA.

SEE MICROSCOPIC AND COMMENT.

SPECIAL STAIN REPORT: MIB-1 PROLIFERATION INDEX: 21%

ADDENDUM DIAGNOSIS:

B. BRAIN, FRONTAL LOBE, EXCISION: MALIGNANT GLIOMA.

ICB-0-3 Recurrence
Glioma, malignant 9380/3
Site: frontal lobe C71.1

Operation/Specimen: UPDATED REPORT - Brain, frontal lobe.

Clinical History and Pre-Op Dx: Recurrent brain tumor.

hw
2/17/15

GROSS PATHOLOGY:

A. Received fresh, one fragment, 0.9 cm across in largest dimension.
Semi-firm, grayish-white. In total #1.

INTRAOPERATIVE CONSULTATION: Brain: Glioma, high histological grade.

B.

SPECIMEN: Frontal lobe tumor.

FIXATIVE: Formalin.

GENERAL: A tan-gray irregular spongy soft tissue fragment 1.5 x
0.8 x 0.4 cm. External surface is tan-gray with
variegated brown hemorrhagic areas. Sectioning reveals
tan-gray smooth cut surface with no gross nodularity.

SECTIONS: 1,2 - all submitted.

MICROSCOPIC: Portions of a neoplastic proliferation of glial cells.
The neoplastic nuclei have features of anaplasia, and are distributed
in a fibrillary background. Mitotic figures are present, and
microvessels show cellular proliferation. There are no areas of
necrosis.

COMMENT: The specimen is a high histological grade glioma devoid of
necrosis (WHO grade IV/IV).

SPECIAL STAINS: Immunoperoxidase methods for GFAP and MIB-1 were
performed on sections from block #1. The GFAP demonstrates the glial
nature of the neoplasm. With the MIB-1 a proliferation index of 21% is
determined.

ADDENDUM REPORT

Requested by:

[page 2 of 2]
MICROSCOPIC DESCRIPTION: Portions of cerebrum with the presence of a focal area of dense fibrocollagenous tissue. This scar tissue is in very close relationship with a neoplasm similar to that one described for part A. In here, the neoplasm is infiltrating diffusely the cerebral cortex.

TISSUE COMMITTEE CODE:

BILLING CODES:

Source: NCI Genomic Data Commons file e154c7c4-82d2-40f8-aade-e2b0224e20b8 (TCGA-06-0221.8B5EF62B-5387-4395-A80D-0986E16DC5C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).